Gene-level copy-number profile of specimen HCM-CSHL-0464-C50-85D from HCMI case HCM-CSHL-0464-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal carcinoma, noninfiltrating, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.0 years (15,330 days).
Specimen HCM-CSHL-0464-C50-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4b50e7e-d8b2-404b-ac63-3edd7ea7f818.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0464-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/1579f7c3-936b-439f-8c12-446c68938b14

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,867; copy number 2: 10,013; copy number 3: 27,352; copy number 4: 12,761; copy number 5: 5,350; copy number 6: 62; copy number 7: 190; copy number 8: 25; copy number 9: 72; copy number 10: 341; copy number 11: 88; copy number 12: 7; copy number 13: 2; copy number 14: 76; copy number 15: 40; copy number 16: 16; copy number 17: 15; copy number 18: 7; copy number 19: 10; copy number 20: 15; copy number 21: 7; copy number 22: 12; copy number 23: 4; copy number 24: 4; copy number 26: 1; copy number 27: 17; copy number 29: 13; copy number 45: 13; copy number 46: 5; copy number 48: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 971 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:187,712,816–188,595,931, 6 genes, copy number 7–10: LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561.
- chr6:122,975,198–123,072,925, 2 genes, copy number 11: AL591428.1, CLVS2.
- chr6:125,577,545–127,681,555, 34 genes, copy number 8–9: AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536.
- chr6:134,074,123–138,988,261, 96 genes, copy number 10 (broad region; genes not listed).
- chr8:37,559,992–37,674,387, 5 genes, copy number 8: AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P.
- chr8:63,651,457–64,369,176, 4 genes, copy number 11 (within-gene range 4–11): AC018953.2, LINC01414, AC069133.1, LINC01289.
- chr12:12,310–38,133, 3 genes, copy number 7: DDX11L8, WASH8P, FAM138D.
- chr17:4,739,833–4,934,438, 13 genes, copy number 14 (within-gene range 2–14): ZMYND15, TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2, MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107.
- chr17:38,419,280–38,512,385, 1 gene, copy number 9 (within-gene range 2–9): ARHGAP23.
- chr17:38,530,031–41,160,748, 150 genes, copy number 9–48 (broad region; genes not listed).
- chr17:49,085,511–51,260,163, 104 genes, copy number 7–29 (within-gene range 2–29) (broad region; genes not listed).
- chr17:57,253,236–57,684,689, 2 genes, copy number 9 (within-gene range 2–9): AC091181.2, MSI2.
- chr17:57,448,218–57,532,355, 3 genes, copy number 9: AC015883.1, AC007431.2, AC007431.3.
- chr17:59,422,088–61,392,838, 60 genes, copy number 9–14 (within-gene range 2–14): LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P, BCAS3, RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1.
- chr17:62,627,670–63,864,379, 48 genes, copy number 15–20: MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7, AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6, DCAF7, RNU6-288P, TACO1, AC046185.2, MAP3K3, EEF1DP7, STRADA, LIMD2, AC046185.3, AC046185.1, CCDC47, DDX42, FTSJ3, PSMC5, SMARCD2, TCAM1P.
- chr17:78,787,381–79,009,867, 10 genes, copy number 9–20: USP36, AC022966.2, RPL9P29, TIMP2, AC022966.1, CEP295NL, AC100788.2, AC100788.1, LGALS3BP, CANT1.
- chr20:51,596,514–55,684,915, 45 genes, copy number 10: ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr20:56,205,052–64,327,972, 249 genes, copy number 10–14 (broad region; genes not listed).
- chr21:13,305,152–21,797,415, 136 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,867. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
